Gene-level copy-number profile of tumor specimen TCGA-09-0364-01A from TCGA case TCGA-09-0364, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 80.1 years (29,262 days).
Specimen TCGA-09-0364-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.3ad89fc4-fa3f-4090-a41c-a46b6aa68cd5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-0364-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bc44ed63-844e-4fa0-ae1a-09f178009d11

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,762; copy number 2: 15,500; copy number 3: 22,798; copy number 4: 13,525; copy number 5: 3,557; copy number 6: 803; copy number 7: 875.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-09-0364-01A-02D-0356-01): tumor purity 0.89, ploidy 3.16, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 875 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:1,970,786–2,697,950, 1 gene, copy number 7 (within-gene range 6–7): CACNA1C.
- chr12:2,217,462–13,278,376, 440 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr13:54,115,783–54,819,238, 6 genes, copy number 7: LINC00458, AL356052.1, MIR1297, RPL13AP25, AL442636.1, AL512655.1.
- chr13:69,700,594–107,867,496, 427 genes, copy number 7 (broad region; genes not listed).
- chr13:107,870,383–107,873,372, 1 gene, copy number 7: AL136964.1.

Autosomal genes at a single copy (total copy number 1): 341. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
